CCDI case PBCMGG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0f24c626-d279-4535-9afc-98677de3c57f

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 2.7 years (970 days).

Biospecimens (3 samples)
- Sample 0DV5RS: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DV5S5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV5SK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
